Gene-level copy-number profile of tumor specimen TCGA-13-0905-01B from TCGA case TCGA-13-0905, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.4 years (18,757 days).
Specimen TCGA-13-0905-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8f5395db-eecc-4317-8f7a-eb7b73388676.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0905-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f41e339-a2e9-465d-a1f9-5bf7a06b57f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 15,854; copy number 2: 35,556; copy number 3: 6,844; copy number 4: 569; copy number 5: 939.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0905-01B-01D-0452-01): tumor purity 0.94, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:150,599,883–150,843,665, 1 gene (within-gene range 0–1): PLEKHG1.
- chr6:150,650,772–151,101,887, 6 genes: AL450344.2, PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2.
- chr10:87,751,512–89,017,059, 30 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1.
- chr13:48,232,612–48,711,226, 14 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 939 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:176,207,648–186,988,981, 204 genes, copy number 5 (broad region; genes not listed).
- chr5:659,862–693,352, 1 gene, copy number 5 (within-gene range 4–5): TPPP.
- chr5:710,355–11,904,446, 215 genes, copy number 5 (broad region; genes not listed).
- chr8:109,362,461–114,791,929, 38 genes, copy number 5 (within-gene range 4–5): PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.
- chr14:90,383,365–105,136,974, 481 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,850. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
